Gene-level copy-number profile of specimen HCM-WCMC-1359-C34-85A from HCMI case HCM-WCMC-1359-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,094 days).
Specimen HCM-WCMC-1359-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05b543b6-8c25-480d-acbd-6c6604cb83cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1359-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,943 have no estimate.
https://portal.gdc.cancer.gov/files/499271ea-5817-48a3-b096-7ee777973ea4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 203; copy number 1: 333; copy number 2: 7,258; copy number 3: 23,561; copy number 4: 23,675; copy number 5: 1,173; copy number 6: 2,108; copy number 7: 135; copy number 8: 43; copy number 9: 41; copy number 10: 11; copy number 16: 8; copy number 19: 21; copy number 21: 65; copy number 24: 45.

Homozygous deletions (total copy number 0; autosomes only): 203 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:22,094,522–22,095,472, 1 gene (within-gene range 0–2): OR4N4.
- chr22:21,759,657–24,008,258, 202 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 191 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes, copy number 9: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr12:32,106,835–32,383,633, 1 gene, copy number 9 (within-gene range 7–9): BICD1.
- chr12:32,339,368–32,646,050, 5 genes, copy number 9: AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P.
- chr14:23,346,306–23,568,073, 17 genes, copy number 9 (within-gene range 1–9): SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1.
- chr15:22,178,107–22,185,402, 2 genes, copy number 10: IGHV1OR15-3, IGHV4OR15-8.
- chr21:8,701,461–8,880,976, 6 genes, copy number 10: CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1.
- chr21:10,328,411–10,358,620, 3 genes, copy number 10: AP003900.1, EIF3FP1, VN1R7P.
- chr22:17,084,954–17,165,445, 6 genes, copy number 9: IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1.
- chr22:18,527,802–18,719,341, 10 genes, copy number 16–21: TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:19,667,023–21,735,794, 129 genes, copy number 19–24 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 333. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
